Somatic mutation profile of tumor specimen MBCProject_0524_T2_WES (aliquot MBCProject_0524_T2_WES_1) from CMI case MBCProject_0524, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 47.9 years (17,478 days).
Specimen MBCProject_0524_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3330d943-75a2-42b6-a06f-6f6a12fac96d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0524_SALIVA (Saliva), aliquot MBCProject_0524_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/addb4d17-f6f6-479b-95b1-421d7287fd82

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, 3'UTR 2, Frame Shift Del 2, Intron 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3145G>A p.G1049S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.704); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 45/209 reads (22%) | hotspot (GDC flag); catalogued as rs1131691026, CM101750, COSV52661500, COSV52987374, COSV53571745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARSB | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs529444755, COSV53719930; called by muse, mutect2
- COL2A1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 98/479 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs144505311; called by muse, mutect2, varscan2
- DCAF13 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs978385936, COSV52574120; called by muse, mutect2
- DES | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 53/444 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770258461, COSV100900481; called by muse, mutect2, varscan2
- IQSEC3 | c.2698G>A p.D900N (on ENST00000538872 / NM_001170738.2; = p.D597N on NM_015232.1) | Missense Mutation (SNP) | VAF 176/253 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1555097198, COSV58282790; called by muse, varscan2
- MYBL2 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 86/2324 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.253); catalogued as COSV99406325, COSV99406406; called by muse, mutect2
- MYH2 | c.3351G>T p.L1117F | Missense Mutation (SNP) | VAF 61/304 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs760655197; called by muse, mutect2, varscan2
- PEX1 | c.957G>C p.Q319H | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99952053; called by muse, mutect2, varscan2
- RBM20 | c.3140C>T p.S1047F | Missense Mutation (SNP) | VAF 55/520 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as rs1237065275; called by muse, mutect2, varscan2
- RBM22 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV52270768; called by muse, mutect2
- SCN8A | c.3914G>A p.R1305K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs61618583; called by muse, varscan2
- TREX2 | c.745G>A p.A249T (on ENST00000334497; = p.A206T on NM_080701.3) | Missense Mutation (SNP) | VAF 80/470 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs782712553; called by muse, mutect2, varscan2
- UHRF1 | c.2257C>T p.R753W (on ENST00000612630 / NM_001290050.1; = p.R766W on NM_013282.4) | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as rs1276112477; called by muse, mutect2
- AEBP1 | c.874A>C p.K292Q | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ATP1A2 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 120/620 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FOXD4L4 | c.896G>T p.C299F | Missense Mutation (SNP) | VAF 158/1022 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR50 | c.1583_1595del p.H528Lfs*61 | Frame Shift Del (DEL) | VAF 34/245 reads (14%) | called by mutect2, pindel
- GRIA4 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); called by muse, varscan2
- PPP1R15B | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- PTGS2 | c.431A>C p.D144A | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2
- SPG11 | c.3832del p.I1278Ffs*2 | Frame Shift Del (DEL) | VAF 22/197 reads (11%) | called by mutect2, varscan2
- TLR7 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZNF689 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- ANKRD26 | c.324C>G p.V108= | Silent (SNP) | VAF 66/290 reads (23%) | called by muse, mutect2, varscan2
- ARID1B | c.5289G>A p.E1763= | Silent (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- CFAP65 | c.531G>A p.K177= (on ENST00000341552 / NM_194302.4; = p.K112= on NM_152389.4) | Silent (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- HCN3 | c.1548A>G p.S516= | Silent (SNP) | VAF 44/460 reads (10%) | called by muse, mutect2
- INA | c.246G>A p.A82= | Silent (SNP) | VAF 23/199 reads (12%) | catalogued as COSV63976408; called by muse, mutect2, varscan2
- LRP5 | c.681G>C p.S227= | Silent (SNP) | VAF 23/386 reads (6%) | called by muse, mutect2
- MOV10 | c.2538A>G p.K846= | Silent (SNP) | VAF 20/358 reads (6%) | called by muse, mutect2
- WNT16 | c.21G>A p.L7= | Silent (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- ZNF341 | c.1899C>T p.R633= (on ENST00000375200 / NM_001282935.1; = p.R626= on NM_032819.4) | Silent (SNP) | VAF 31/314 reads (10%) | called by muse, mutect2, varscan2
- ZNF469 | c.11562G>A p.P3854= (on ENST00000437464; = p.P3882= on NM_001367624.2) | Silent (SNP) | VAF 46/536 reads (9%) | catalogued as rs534962147; called by muse, mutect2
- H3-4 | c.*30G>A | 3'UTR (SNP) | VAF 24/237 reads (10%) | catalogued as rs759918684, COSV64211001; called by muse, mutect2, varscan2
- PDE6B | c.927+37C>T | Intron (SNP) | VAF 13/81 reads (16%) | catalogued as rs373065560; called by muse, mutect2, varscan2
- POLR2J | c.*24C>G | 3'UTR (SNP) | VAF 17/127 reads (13%) | called by muse, mutect2, varscan2
- RPL37AP1 | chr20:44461997 C>T | 3'Flank (SNP) | VAF 25/230 reads (11%) | catalogued as rs569712213; called by muse, mutect2, varscan2
